Somatic mutation profile of tumor specimen 0DSWZ6 from CCDI case PBCICS, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Oligodendroglioma, NOS; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 14.3 years (5,206 days).
Specimen 0DSWZ6: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f5d827c4-a1ef-4fff-be55-351d769f845e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DSWYZ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3203da48-de59-49f7-93e4-a9855955d17c

The open-access MAF lists 18 somatic variants for this specimen: 11 protein-altering or splice-affecting, 5 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 9, Silent 5, Intron 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CIC | c.4535G>A p.R1512H | Missense Mutation (SNP) | VAF 51/203 reads (25%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV50554672, COSV50623937; called by muse, mutect2, varscan2
- IDH1 | c.395G>A p.R132H | Missense Mutation (SNP) | VAF 205/516 reads (40%) | hotspot (GDC flag); SIFT deleterious, low confidence (0.01); PolyPhen benign (0.047); catalogued as rs121913500, CM1310533, COSV61615239, COSV61615420; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PDHB | c.961C>T p.P321S | Missense Mutation (SNP) | VAF 98/766 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs772328849; called by muse, mutect2, varscan2
- ZFR2 | c.448G>A p.A150T | Missense Mutation (SNP) | VAF 30/164 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.175); catalogued as rs779917513; called by muse, mutect2, varscan2
- BTNL9 | c.614C>T p.A205V | Missense Mutation (SNP) | VAF 25/223 reads (11%) | SIFT tolerated (0.16); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- CIC | c.146_147insG p.D50* | Frame Shift Ins (INS) | VAF 26/227 reads (11%) | called by mutect2, varscan2
- LATS2 | c.2968G>A p.V990I | Missense Mutation (SNP) | VAF 29/295 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- LIG1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 29/249 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.217); called by muse, mutect2, varscan2
- MED23 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 90/594 reads (15%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.777); called by muse, mutect2, varscan2
- POLR1G | c.1515G>C p.Q505H | Missense Mutation (SNP) | VAF 6/122 reads (5%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); called by muse, mutect2
- ZNF438 | c.2102G>A p.W701* | Nonsense Mutation (SNP) | VAF 82/472 reads (17%) | called by muse, mutect2, varscan2
- DYRK2 | c.342G>T p.V114= (on ENST00000344096 / NM_006482.3; = p.V41= on NM_003583.4) | Silent (SNP) | VAF 47/431 reads (11%) | called by muse, mutect2, varscan2
- FRMD3 | c.1473C>T p.N491= | Silent (SNP) | VAF 52/863 reads (6%) | catalogued as rs369661439; called by muse, mutect2
- MRGPRG | c.129G>A p.K43= | Silent (SNP) | VAF 19/77 reads (25%) | catalogued as rs1375364627, COSV100183109; called by muse, mutect2, varscan2
- OR51I2 | c.96C>T p.C32= | Silent (SNP) | VAF 168/457 reads (37%) | catalogued as rs201440151, COSV58300095; called by muse, mutect2, varscan2
- SIGLEC7 | c.1068C>T p.V356= | Silent (SNP) | VAF 54/111 reads (49%) | catalogued as rs377201615; called by muse, mutect2, varscan2
- DAPP1 | c.774+491A>T | Intron (SNP) | VAF 260/819 reads (32%) | called by muse, mutect2, varscan2
- ETNK1 | c.416+243C>T | Intron (SNP) | VAF 104/1640 reads (6%) | catalogued as rs780356905, COSV56885404; called by muse, mutect2
